Gene-level copy-number profile of tumor specimen TCGA-VQ-A92D-01A from TCGA case TCGA-VQ-A92D, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 67.3 years (24,595 days).
Specimen TCGA-VQ-A92D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.3bea9b4a-09ab-4d7a-a5e6-917003d46276.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A92D-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 823 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/806a1835-e765-4a1e-b2a2-b5d32a419fa8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,419; copy number 2: 34,711; copy number 3: 15,056; copy number 4: 3,224; copy number 5: 1,755; copy number 6: 930; copy number 7: 378; copy number 8: 96; copy number 9: 59; copy number 10: 78; copy number 11: 94.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A92D-01A-11D-A40Z-01): tumor purity 0.7, ploidy 2.44, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,361 genes in 70 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:32,679,906–33,431,052, 29 genes, copy number 5 (within-gene range 3–5): SYNC, AC114489.1, KIAA1522, YARS1, S100PBP, FNDC5, HPCA, TMEM54, AL031602.2, RNF19B, AL031602.1, AL355864.1, AL355864.2, AL020995.1, AK2, Metazoa_SRP, AZIN2, AL662907.1, TRIM62, AL662907.2, AL662907.3, ZNF362, AL513327.2, A3GALT2, AL513327.1, PHC2, MIR3605, RN7SKP16, PHC2-AS1.
- chr1:143,343,180–152,806,628, 389 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr1:164,769,116–165,911,618, 26 genes, copy number 5 (within-gene range 3–5): PBX1-AS1, AL357568.1, Y_RNA, RPL35AP7, RNU6-755P, LMX1A, LMX1A-AS2, LMX1A-AS1, RXRG, LRRC52-AS1, PRELID1P7, LRRC52, AL356441.2, AL356441.1, MGST3, ALDH9A1, Y_RNA, AL451074.3, AL451074.2, AL451074.1, AL451074.5, TMCO1, TMCO1-AS1, AL451074.4, UCK2, AL358115.1.
- chr1:211,082,872–212,791,782, 55 genes, copy number 6 (within-gene range 3–6): AC092017.2, AC092017.3, KCNH1-IT1, AC092017.1, PRELID1P5, RCOR3, TRAF5, AL590101.1, LINC00467, SNX25P1, ARPC3P2, RD3, AC105275.1, SLC30A1, AC105275.2, AL356310.1, LINC01693, NEK2, FDPSP8, AC096637.2, AC096637.1, LPGAT1, RN7SL344P, Y_RNA, LPGAT1-AS1, AC092814.2, INTS7, AC092814.1, DTL, RPL21P28, MIR3122, RN7SKP98, AL606468.1, LINC02608, PPP2R5A, AL360091.2, AL360091.3, RPL23AP18, SNORA16B, AL360091.1, PACC1, AC092803.3, NENF, LINC02771, AC092803.2, LINC01740, AC092803.1, AC092803.4, ATF3, AL590648.2, FAM71A, AL590648.1, LINC02773, BATF3, NSL1.
- chr1:225,401,502–226,227,060, 28 genes, copy number 5: LBR, LINC02765, AC092811.1, ENAH, AC099066.2, AC099066.1, RNU6-1304P, SRP9, AC099066.3, EPHX1, AL591895.1, TMEM63A, LEFTY1, AL117348.2, PYCR2, MIR6741, AL117348.1, LEFTY2, NDUFA3P3, SDE2, AL512343.2, H3-3A, LINC01703, AL512343.1, ACBD3, ACBD3-AS1, AL592045.1, MIXL1.
- chr1:234,356,704–236,502,915, 70 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr2:69,103,682–70,103,220, 24 genes, copy number 7: MIR3126, RNA5SP96, RNU6-1216P, AC112230.1, GFPT1, Y_RNA, NFU1, AAK1, RN7SL604P, SNORA36C, RPL36AP16, B3GALNT1P1, ANXA4, AC092431.1, GMCL1, AC019206.1, RPL23AP92, SNRNP27, MXD1, ASPRV1, PCBP1-AS1, RN7SL470P, PCBP1, AC016700.1.
- chr2:177,283,508–178,779,963, 30 genes, copy number 5 (within-gene range 2–5): AC019080.1, AC019080.3, AC019080.4, MIR6512, AC019080.5, H3P7, AC019080.2, AGPS, TTC30B, AC073834.1, TTC30A, PDE11A, PDE11A, PDE11A-AS1, AC011998.2, API5P2, SDHDP5, RNU6-629P, CYCTP, AC011998.1, RBM45, RNU5E-9P, OSBPL6, CHROMR, PRKRA, PJVK, NUDCP2, FKBP7, PLEKHA3, TTN-AS1.
- chr5:72,816,312–74,536,976, 36 genes, copy number 6 (within-gene range 3–6): TNPO1, MIR4804, RPL35AP13, AC008972.1, AC008972.2, FCHO2, AC020893.1, CHP1P1, TMEM171, AC116345.3, AC116345.2, TMEM174, AC116345.4, AC116345.1, LINC02230, AC099522.1, FOXD1, FOXD1-AS1, LINC01385, LINC01386, AC099522.2, BTF3, FUNDC2P1, ANKRA2, UTP15, ARHGEF28, AC091868.2, AC091868.1, RNU7-196P, AC093283.1, LINC02122, LINC01331, LINC01335, RN7SL814P, LINC01333, LINC01332.
- chr6:29,497,475–31,862,905, 225 genes, copy number 5–6 (broad region; genes not listed).
- chr6:41,683,978–45,377,953, 125 genes, copy number 7–10 (within-gene range 3–10) (broad region; genes not listed).
- chr7:5,419,827–6,161,564, 30 genes, copy number 6: AC093620.1, AC092171.1, AC092171.4, AC092171.3, AC092171.5, FBXL18, AC092171.2, MIR589, ACTB, AC006483.2, AC006483.1, FSCN1, RNF216, RNF216-IT1, MIR6874, ZNF815P, RN7SL556P, OCM, CCZ1, RSPH10B, PMS2, Y_RNA, AIMP2, SNORA80D, EIF2AK1, ANKRD61, RN7SL851P, RNU6-218P, AC004895.1, USP42.
- chr7:98,106,862–101,301,346, 155 genes, copy number 6 (broad region; genes not listed).
- chr8:27,732,915–29,360,222, 44 genes, copy number 5–7: AC013643.2, CCDC25, ESCO2, RNU6-1276P, PBK, AC104997.1, SCARA5, MIR4287, AC069113.1, AC069113.3, AC069113.2, NUGGC, ELP3, AC021678.1, AC021678.3, AC021678.2, RPL5P22, PNOC, ZNF395, FBXO16, AC025871.3, AC025871.2, RNU6-178P, AC025871.1, FZD3, MIR4288, RNA5SP259, EXTL3, EXTL3-AS1, INTS9, INTS9-AS1, AC040975.1, HMBOX1, Metazoa_SRP, HMBOX1-IT1, RNA5SP260, AC108449.2, KIF13B, AC108449.3, AC108449.1, HMGB1P23, DUSP4, AC084262.2, AC084262.1.
- chr8:126,474,189–128,187,101, 32 genes, copy number 6 (within-gene range 4–6): AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208.
- chr9:127,920,881–129,791,837, 91 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr10:74,506,081–75,431,588, 29 genes, copy number 6: AC022540.1, MRPL35P3, Y_RNA, NDUFA8P1, POLR3DP1, FAM32CP, AC063962.1, KAT6B, AC018511.2, AC018511.1, DUSP29, AC018511.6, PPIAP13, DUSP13, SAMD8, RPS26P42, VDAC2, COMTD1, ZNF503-AS1, RPL39P25, HMGA1P5, AC010997.3, AC010997.1, SPA17P1, ZNF503, ZNF503-AS2, AC010997.5, AC010997.4, AC010997.2.
- chr10:123,323,422–126,009,592, 55 genes, copy number 6–8: AL160290.2, LINC02641, AL160290.1, AL357127.2, AL357127.1, GPR26, CPXM2, AC009987.1, AC068058.1, BX469938.1, YBX2P1, AL683842.1, CHST15, OAT, NKX1-2, AL445237.1, LHPP, RPS10P18, AC068896.1, FAM53B, AL513190.1, FAM53B-AS1, EEF1AKMT2, Y_RNA, ABRAXAS2, Y_RNA, NPM1P31, AL731577.2, ZRANB1, AL731577.1, CTBP2, AL731571.1, MIR4296, AL157888.1, MRPS21P6, RPS27P18, TEX36-AS1, TEX36, ALDOAP2, AL158835.1, EDRF1-DT, AL158835.3, AL158835.2, EDRF1, EDRF1-AS1, MMP21, UROS, MIR4484, BCCIP, DHX32, Metazoa_SRP, RNU2-42P, FANK1, GNG10P1, FANK1-AS1.
- chr11:45,921,621–47,449,143, 52 genes, copy number 5–9 (within-gene range 3–9): LARGE2, PHF21A, AC024475.1, AC024475.3, AC024475.2, LINC02710, AC116021.1, LINC02489, CREB3L1, DGKZ, MIR4688, MDK, CHRM4, AMBRA1, AC024293.1, MIR3160-1, MIR3160-2, AC127035.1, HARBI1, ATG13, ARHGAP1, ZNF408, F2, CKAP5, MIR5582, AC115088.1, SNORD67, LRP4-AS1, LRP4, AC021573.1, C11orf49, AC103792.1, AC090589.2, ARFGAP2, AC090589.3, PACSIN3, MIR6745, AC090589.1, DDB2, AC018410.1, ACP2, NR1H3, MADD, MADD-AS1, AC090582.1, MYBPC3, SPI1, AC090559.1, MIR4487, SLC39A13, PSMC3, RAPSN.
- chr11:69,641,156–70,436,584, 27 genes, copy number 7: CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:75,911,204–77,126,155, 30 genes, copy number 5 (within-gene range 2–5): PPP1R1AP1, AP003168.2, RNA5SP344, AP003168.1, AP002340.1, WNT11, AP000785.1, LINC02761, THAP12, GVQW3, Y_RNA, AP002360.1, EMSY, AP001189.2, LINC02757, AP001189.5, AP001189.3, AP001189.1, LRRC32, AP001189.4, GUCY2EP, AP003119.1, TSKU, AP003119.2, AP003119.3, ACER3, AP002498.1, B3GNT6, CAPN5, OMP.
- chr12:109,997,419–112,013,185, 55 genes, copy number 5 (within-gene range 4–5): AC084876.2, ANKRD13A, C12orf76, AC007546.1, AC007546.3, AC007546.2, IFT81, ATP2A2, RN7SL769P, ANAPC7, AC144548.1, HMGA1P3, ARPC3, GPN3, RPL31P49, FAM216A, VPS29, AC002350.1, AC002350.2, RAD9B, PPTC7, TCTN1, RN7SL387P, HVCN1, PPP1CC, AC144522.1, AC002375.1, RPL29P25, CCDC63, MYL2, LINC01405, AC002351.1, CUX2, MIR6760, RNA5SP373, PHETA1, LINC02356, HSPA8P14, SH2B3, ATXN2, U7, IFITM3P5, ATXN2-AS, BRAP, PCNPP1, ACAD10, AC002996.1, ALDH2, MIR6761, MAPKAPK5-AS1, MAPKAPK5, RPS2P41, ADAM1A, ADAM1B, TMEM116.
- chr12:120,127,202–122,527,000, 106 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr13:50,862,172–54,986,720, 76 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr14:49,373,966–51,436,963, 76 genes, copy number 6–7 (broad region; genes not listed).
- chr14:75,002,921–76,826,246, 52 genes, copy number 5 (within-gene range 3–5): EIF2B2, AL049780.1, AL049780.3, MLH3, RNU6-689P, ACYP1, ZC2HC1C, NEK9, HIF1AP1, AL049780.2, TMED10, AL691403.2, RNU4ATAC14P, AL691403.1, AF111167.1, U2, FOS, DPPA5P4, LINC01220, AF111167.2, JDP2, BATF, AC007182.1, FLVCR2, AC007182.2, RNA5SP387, AC007182.3, TTLL5, ERG28, AF107885.2, AF107885.1, IFT43, TGFB3, TGFB3-AS1, AC008015.1, AC016526.4, GPATCH2L, AC016526.2, AC016526.3, AC016526.1, ESRRB, AC008050.1, CYCSP1, RPSAP3, AC007376.1, AC007376.2, VASH1, AF111169.3, AF111169.1, VASH1-AS1, ANGEL1, AF111169.4.
- chr15:34,358,633–35,238,197, 33 genes, copy number 6: LPCAT4, ACTG1P15, GOLGA8A, MIR1233-1, AC025678.1, AC025678.2, AC025678.3, HNRNPLP2, FSCN1P1, DNM1P5, GOLGA8B, MIR1233-2, AC027139.1, AC100834.1, LINC02252, AC100834.2, GJD2, AC087457.1, ACTC1, TUBAP11, AQR, AC018868.1, ZNF770, AC114546.3, AC114546.1, AC114546.4, AC114546.2, AC021231.3, NANOGP8, AC021231.2, AC021231.1, PRELID1P4, ANP32AP1.
- chr15:79,668,342–80,773,135, 38 genes, copy number 5: AC023968.1, AC026826.3, AC026826.1, AC026826.2, RNU6-667P, AC021483.1, MTHFS, AC021483.2, ST20-MTHFS, AC015871.4, AC015871.6, ST20, AC015871.7, AC015871.3, ST20-AS1, AC015871.8, AC015871.1, BCL2A1, AC015871.2, AC015871.5, AC092701.1, Metazoa_SRP, ZFAND6, FAH, AC087761.1, CTXND1, LINC00927, AC016705.2, ARNT2, AC016705.1, AC016705.3, AC108451.1, AC108451.2, MIR5572, RNU6-380P, ABHD17C, AC023302.1, AC023302.2.
- chr16:68,686,399–70,660,682, 76 genes, copy number 6 (broad region; genes not listed).
- chr17:38,765,689–41,823,213, 187 genes, copy number 6–11 (within-gene range 2–11) (broad region; genes not listed).
- chr17:58,556,678–62,627,590, 129 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr17:72,627,231–73,836,019, 25 genes, copy number 5: RPL32P33, AC080037.2, SLC39A11, RN7SKP180, AC080037.1, AC011120.1, ATG12P1, POLR3KP2, AC097641.1, SSTR2, COG1, AC097641.2, FAM104A, C17orf80, AC087301.1, CPSF4L, CDC42EP4, SDK2, AC124804.1, AC032019.1, AC032019.2, AC125421.1, LINC00469, LINC02092, AC125421.2.
- chr18:1,883,524–3,278,461, 31 genes, copy number 5 (within-gene range 2–5): AP005230.1, AIDAP3, AP005136.4, METTL4, AP005136.1, AP005136.3, AP005136.2, NDC80, KATNBL1P3, Y_RNA, RNU6-340P, CBX3P2, SMCHD1, AP001011.1, Y_RNA, EMILIN2, LPIN2, AP000919.3, CHORDC1P4, AP000919.1, AP000919.2, SNRPCP4, AP005431.1, SNORA70, MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B.
- chr19:463,346–2,503,141, 139 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr19:11,797,667–14,171,267, 150 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr19:44,085,213–45,305,284, 65 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr20:3,888,839–7,371,692, 76 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr20:17,187,510–18,505,066, 45 genes, copy number 6: RNU6-27P, AL359511.1, RNU1-131P, AL359511.2, AL359511.3, PCSK2, DYNLT3P1, BFSP1, RPS27AP2, AL132765.2, DSTN, RN7SKP69, AL132765.1, RRBP1, BANF2, AL035045.1, RNU6-192P, SNX5, OVOL2, SNORD17, MGME1, PTMAP3, AL160411.1, RPL15P1, RNU7-137P, Y_RNA, KAT14, PET117, GGCTP2, RN7SL14P, RNU2-56P, AL049646.2, ZNF133, AL049646.1, RN7SKP74, ZNF133-AS1, LINC00851, DZANK1, GCNT1P1, RNA5SP476, POLR3F, MIR3192, RPL21P3, RBBP9, RPS19P1.
- chr20:22,960,534–26,251,546, 105 genes, copy number 5–9 (broad region; genes not listed).
- chr20:43,189,998–45,976,075, 122 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,600. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
